Somatic mutation profile of tumor specimen TARGET-30-PARNNG-01A (aliquot TARGET-30-PARNNG-01A-01D) from TARGET case TARGET-30-PARNNG, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Thorax, NOS; Age at diagnosis: 3.7 years (1,336 days).
Specimen TARGET-30-PARNNG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a555cdff-e614-4782-8f0b-a25c664bf4be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PARNNG-10A (Blood Derived Normal), aliquot TARGET-30-PARNNG-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e5ea90a-9253-49b0-88b6-bb859575fcba

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 5, Silent 4, Nonsense Mutation 2, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CMYA5 | c.7130C>A p.S2377* | Nonsense Mutation (SNP) | VAF 20/53 reads (38%) | catalogued as COSV71404983; called by muse, mutect2, varscan2
- DDX20 | c.553G>T p.V185F | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63831446; called by muse, mutect2, varscan2
- DMRT3 | c.673G>A p.A225T | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.053); catalogued as rs757538425, COSV51906658; called by muse, mutect2, varscan2
- PLCXD2 | c.695C>T p.A232V | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs576180075, COSV67339450; called by muse, mutect2, varscan2
- PTPRZ1 | c.4620G>A p.W1540* | Nonsense Mutation (SNP) | VAF 8/47 reads (17%) | catalogued as COSV66441994; called by muse, mutect2, varscan2
- TLN2 | c.3645G>C p.L1215F | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.641); catalogued as COSV60887403, COSV60892646; called by muse, mutect2, varscan2
- WASF2 | c.904C>A p.P302T | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as COSV71006267; called by muse, mutect2, varscan2
- ALMS1 | c.1435_1436insT p.D479Vfs*4 | Frame Shift Ins (INS) | VAF 10/36 reads (28%) | called by mutect2, varscan2
- ZBTB37 | c.969_977del p.R323_R325del | In Frame Del (DEL) | VAF 10/42 reads (24%) | called by mutect2, pindel, varscan2
- AC006059.2 | c.252C>T p.H84= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as rs753389713, COSV59608384; called by muse, mutect2, varscan2
- C8orf74 | c.699G>T p.L233= | Silent (SNP) | VAF 18/157 reads (11%) | catalogued as COSV58755032; called by muse, mutect2, varscan2
- MPP2 | c.918C>A p.L306= (on ENST00000461854 / NM_001278372.2; = p.L282= on NM_005374.5) | Silent (SNP) | VAF 24/131 reads (18%) | catalogued as COSV52238114; called by muse, mutect2, varscan2
- PPP2R2D | c.777G>C p.L259= | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as COSV101409063, COSV70779446; called by muse, mutect2, varscan2
